Somatic mutation profile of tumor specimen ALCH-ABFP-TTP1-A (aliquot ALCH-ABFP-TTP1-A-1-0-D-A486-36) from ALCHEMIST case ALCH-ABFP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.9 years (17,511 days).
Specimen ALCH-ABFP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5447b1af-8aa2-4216-88fb-92c1089edc77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABFP-NB1-A (Blood Derived Normal), aliquot ALCH-ABFP-NB1-A-1-0-D-A486-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfc18b9f-98f1-4262-ba95-da8df5319f1e

The open-access MAF lists 75 somatic variants for this specimen: 54 protein-altering or splice-affecting, 11 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 11, Intron 6, Nonsense Mutation 3, Splice Region 3, RNA 2, In Frame Del 2, Frame Shift Del 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 174/649 reads (27%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- L1CAM | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 234/762 reads (31%) | catalogued as rs1557091773, CM970857, COSV62828861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 284/705 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CFH | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 23/495 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661677; called by muse, mutect2
- CLDN12 | c.113T>G p.L38W | Missense Mutation (SNP) | VAF 12/372 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99842006; called by muse, mutect2
- ELN | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 44/1006 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV52716968; called by muse, mutect2
- ESPN | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 311/991 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.381); catalogued as COSV64705317; called by muse, mutect2, varscan2
- EXOC3 | c.102G>C p.R34S | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV59267434; called by muse, mutect2, varscan2
- F8 | c.410C>A p.T137N | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM950388; called by muse, mutect2, varscan2
- MAP1S | c.2705G>A p.R902Q | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs753996400, COSV60723869; called by muse, mutect2, varscan2
- MOGS | c.2056del p.V686* | Frame Shift Del (DEL) | VAF 53/358 reads (15%) | catalogued as COSV51968519; called by mutect2, pindel, varscan2
- NUBPL | c.754C>G p.H252D | Missense Mutation (SNP) | VAF 22/756 reads (3%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.627); catalogued as rs1184273101; called by muse, mutect2
- NYX | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs756209419, COSV100699373; called by muse, mutect2, varscan2
- PAH | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 60/322 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); catalogued as COSV61013953; called by muse, mutect2, varscan2
- PLEC | c.9461G>A p.R3154Q (on ENST00000322810 / NM_201380.4; = p.R3044Q on NM_000445.5) | Missense Mutation (SNP) | VAF 50/776 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs782025276; called by muse, mutect2
- PLXNB2 | c.2713G>A p.G905R | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1436129405; called by muse, mutect2, varscan2
- SCN2A | c.2860G>T p.A954S | Missense Mutation (SNP) | VAF 176/627 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs749485469, COSV99331595; called by muse, mutect2, varscan2
- SLCO1B1 | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV57012414; called by muse, mutect2, varscan2
- SLITRK5 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61521102; called by muse, mutect2
- STK3 | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV69223413, COSV69225505; called by muse, mutect2, varscan2
- TAZ | c.542-3C>T | Splice Region (SNP) | VAF 78/1064 reads (7%) | catalogued as rs781795144; called by muse, mutect2
- TP53AIP1 | c.348G>C p.Q116H | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV101513115; called by muse, mutect2, varscan2
- TSC22D1 | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs748065714, COSV71775803; called by muse, mutect2, varscan2
- VEZT | c.800G>A p.R267K | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV54138028; called by muse, mutect2, varscan2
- WNT7B | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 26/586 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.086); catalogued as rs1164975115, COSV59748762, COSV59751895; called by muse, mutect2
- ZNF429 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV61918791; called by muse, mutect2, varscan2
- ACTN2 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 24/711 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- C16orf96 | c.3415_3417del p.A1139del | In Frame Del (DEL) | VAF 45/239 reads (19%) | called by mutect2, pindel, varscan2
- CAPRIN1 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 42/330 reads (13%) | called by muse, varscan2
- CCDC159 | c.22-7T>A | Splice Region (SNP) | VAF 102/298 reads (34%) | called by muse, mutect2, varscan2
- CHPF2 | c.941T>C p.M314T | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CLDN20 | c.332G>C p.R111T | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.005); called by muse, mutect2
- DGKI | c.1871G>T p.G624V | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- DTNBP1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 85/1499 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2
- FAM126A | c.1169G>C p.G390A | Missense Mutation (SNP) | VAF 25/519 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2
- FAM167B | c.230A>G p.D77G | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, varscan2
- FRMPD4 | c.1832G>A p.S611N | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.022); called by muse, mutect2
- GDI1 | c.820-3C>A | Splice Region (SNP) | VAF 32/738 reads (4%) | called by muse, mutect2
- ITGA7 | c.2056A>C p.I686L (on ENST00000555728; = p.I642L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/304 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- ITGAD | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- KDM3A | c.751T>C p.C251R | Missense Mutation (SNP) | VAF 47/309 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- LGR5 | c.1223A>G p.N408S | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZD2 | c.7545G>C p.E2515D | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- PKHD1L1 | c.1492C>A p.Q498K | Missense Mutation (SNP) | VAF 23/572 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2
- RALGAPA1 | c.4645C>G p.P1549A | Missense Mutation (SNP) | VAF 119/422 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RXRB | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 35/345 reads (10%) | called by muse, mutect2, varscan2
- SMARCA4 | c.3043G>T p.G1015C | Missense Mutation (SNP) | VAF 24/826 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMG7 | c.2906C>T p.S969L | Missense Mutation (SNP) | VAF 38/582 reads (7%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); called by muse, mutect2
- TRIM41 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 54/978 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.303); called by muse, mutect2
- TRIP13 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TTN | c.4162G>C p.G1388R (on ENST00000591111; = p.G1342R on NM_003319.4) | Missense Mutation (SNP) | VAF 128/695 reads (18%) | PolyPhen benign (0.021); called by muse, mutect2, varscan2
- UBA1 | c.2618A>C p.Y873S | Missense Mutation (SNP) | VAF 32/1002 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZMAT1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ZNF804B | c.1441G>C p.D481H | Missense Mutation (SNP) | VAF 90/525 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DOP1B | c.5034C>T p.P1678= | Silent (SNP) | VAF 82/374 reads (22%) | called by muse, varscan2
- EVI2B | c.495T>C p.N165= | Silent (SNP) | VAF 85/380 reads (22%) | called by muse, mutect2, varscan2
- EXOC3 | c.606C>T p.V202= | Silent (SNP) | VAF 67/432 reads (16%) | catalogued as rs1278637567; called by muse, mutect2, varscan2
- GAREM1 | c.366C>T p.V122= | Silent (SNP) | VAF 38/263 reads (14%) | called by muse, mutect2, varscan2
- INSYN1 | c.213C>T p.D71= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as rs1365848899, COSV65837527; called by muse, mutect2
- KHNYN | c.162G>A p.L54= | Silent (SNP) | VAF 54/261 reads (21%) | called by muse, mutect2, varscan2
- KMT2B | c.5949G>T p.V1983= | Silent (SNP) | VAF 110/638 reads (17%) | called by muse, mutect2, varscan2
- MEMO1 | c.699C>T p.S233= | Silent (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- RIOX2 | c.960G>A p.E320= (on ENST00000333396 / NM_001042533.2; = p.E319= on NM_032778.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/354 reads (10%) | called by muse, varscan2
- TAF6L | c.889C>T p.L297= | Silent (SNP) | VAF 34/203 reads (17%) | called by muse, mutect2, varscan2
- TNXB | c.2313G>A p.P771= | Silent (SNP) | VAF 94/997 reads (9%) | catalogued as rs758324098; called by muse, mutect2
- AC074085.2 | n.258G>T | RNA (SNP) | VAF 64/515 reads (12%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9155G>A | Intron (SNP) | VAF 104/1610 reads (6%) | called by muse, mutect2
- AC244517.10 | c.36-8836C>T | Intron (SNP) | VAF 54/1272 reads (4%) | catalogued as COSV73145192; called by muse, mutect2
- AL132655.6 | chr20:58840878 T>A | 5'Flank (SNP) | VAF 178/1330 reads (13%) | called by muse, mutect2, varscan2
- CAV1 | c.30+137C>G | Intron (SNP) | VAF 200/1193 reads (17%) | called by muse, mutect2, varscan2
- CLCA3P | n.498C>T | RNA (SNP) | VAF 32/315 reads (10%) | called by muse, mutect2, varscan2
- DNAJC13 | c.5485+22T>C | Intron (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- HNF1B | c.*57C>T | 3'UTR (SNP) | VAF 58/732 reads (8%) | catalogued as rs1272071787; called by muse, mutect2
- PRRC2A | c.112+206C>T | Intron (SNP) | VAF 18/191 reads (9%) | catalogued as rs1346891823; called by muse, mutect2
- TEX35 | c.586+20A>T | Intron (SNP) | VAF 60/463 reads (13%) | called by muse, mutect2, varscan2
